CCDI case PBBSVA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/6ebc983b-3afb-45da-aa0e-5228009b7d87

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Vertebral column; Age at diagnosis: 6.6 years (2,405 days).

Biospecimens (3 samples)
- Sample 0DG84G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG853: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG87S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
